Somatic mutation profile of tumor specimen TCGA-KN-8419-01A (aliquot TCGA-KN-8419-01A-11D-2310-10) from TCGA case TCGA-KN-8419, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 43.2 years (15,769 days).
Specimen TCGA-KN-8419-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2982165-c8c0-454d-bd68-7f7128b58727.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KN-8419-11A (Solid Tissue Normal), aliquot TCGA-KN-8419-11A-01D-2310-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9fcac126-edf9-4eb7-adfb-5866ee4c7870

The open-access MAF lists 17 somatic variants for this specimen: 7 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 6, Missense Mutation 6, 3'UTR 3, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDC | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1261689439, COSV100779128; called by muse, mutect2
- DSG1 | c.1957G>A p.G653R | Missense Mutation (SNP) | VAF 44/79 reads (56%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); catalogued as COSV57135579; called by muse, mutect2, varscan2
- GIMAP8 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs576578780, COSV56231919; called by muse, mutect2
- NAA40 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 58/117 reads (50%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.717); catalogued as rs749778061, COSV58161517; called by muse, mutect2, varscan2
- OASL | c.253G>T p.V85L | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV99984649; called by muse, mutect2, varscan2
- SPTB | c.4474-1G>A p.X1492_splice | Splice Site (SNP) | VAF 20/100 reads (20%) | catalogued as rs1311265074, COSV101072404; called by muse, mutect2
- ZCCHC2 | c.3106A>T p.N1036Y | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- ARHGAP45 | c.480C>A p.V160= | Silent (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
- CRACD | c.3009G>A p.P1003= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs369933689; called by muse, mutect2, varscan2
- CTH | c.831C>A p.A277= | Silent (SNP) | VAF 30/106 reads (28%) | called by muse, mutect2, varscan2
- KRT84 | c.654C>T p.I218= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as COSV99231037; called by muse, mutect2, varscan2
- OSBP2 | c.867C>T p.D289= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs376288614; called by muse, mutect2, varscan2
- UBXN4 | c.651A>G p.E217= | Silent (SNP) | VAF 3/27 reads (11%) | catalogued as COSV99739601; called by muse, mutect2
- ADO | c.*1921A>T | 3'UTR (SNP) | VAF 26/60 reads (43%) | catalogued as COSV99654291; called by muse, mutect2, varscan2
- FMN1 | c.2044-2204G>A | Intron (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- SLC45A4 | c.*14C>T | 3'UTR (SNP) | VAF 12/112 reads (11%) | catalogued as rs906200229; called by mutect2, varscan2
- ZFP3 | c.*3237_*3240del | 3'UTR (DEL) | VAF 23/62 reads (37%) | called by mutect2, pindel, varscan2
